Somatic mutation profile of tumor specimen BA2805D (aliquot aq-BA2805D) from BEATAML1.0 case 2174, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 83.5 years (30,481 days).
Specimen BA2805D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 12a0947b-92f8-4736-b2b7-54c7b35a78a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2544D (Solid Tissue Normal), aliquot aq-BA2544D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51e6ae36-6246-4fc7-81cc-d1b59359641c

The open-access MAF lists 12 somatic variants for this specimen: 7 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 4, Nonsense Mutation 2, Splice Site 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH18 | c.1513-1G>A p.X505_splice | Splice Site (SNP) | VAF 38/86 reads (44%) | catalogued as COSV56926793; called by muse, mutect2, varscan2
- DNMT3A | c.2678G>A p.W893* | Nonsense Mutation (SNP) | VAF 51/55 reads (93%) | catalogued as rs750515748, COSV53039322, COSV53041651, COSV53048797; called by muse, mutect2, varscan2
- EPGN | c.138C>A p.D46E | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs1297067305; called by muse, mutect2
- KIF26B | c.4014C>A p.D1338E | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs767408000, COSV63641576; called by muse, mutect2
- UBASH3B | c.20C>A p.P7H | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV52494233; called by muse, mutect2
- CLDN5 | c.304G>T p.A102S (on ENST00000618236 / NM_001363066.2; = p.A187S on NM_003277.4) | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.758); called by muse, mutect2
- LCT | c.4717A>T p.K1573* | Nonsense Mutation (SNP) | VAF 44/103 reads (43%) | called by mutect2, varscan2
- ALOX15 | c.1392G>T p.A464= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as rs1415444236, COSV53401892, COSV99541745; called by muse, mutect2
- OR5A2 | c.391T>C p.L131= | Silent (SNP) | VAF 38/95 reads (40%) | called by muse, mutect2, varscan2
- SPOCD1 | c.1803G>A p.K601= | Silent (SNP) | VAF 28/71 reads (39%) | catalogued as rs753220172; called by muse, varscan2
- ZNF717 | c.480T>C p.N160= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as rs1015141252, COSV68863597; called by muse, mutect2
- HID1 | c.1637-65A>T | Intron (SNP) | VAF 22/38 reads (58%) | called by muse, mutect2, varscan2
